Somatic mutation profile of tumor specimen TCGA-63-7022-01A (aliquot TCGA-63-7022-01A-11D-1945-08) from TCGA case TCGA-63-7022, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA.
Specimen TCGA-63-7022-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58d560c8-5a60-48c4-8214-0be7ca523b5d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-63-7022-10A (Blood Derived Normal), aliquot TCGA-63-7022-10A-01D-1945-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd2d366f-2bca-496b-b7a3-d9217f8ebd6e

The open-access MAF lists 203 somatic variants for this specimen: 142 protein-altering or splice-affecting, 53 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 119, Silent 53, Nonsense Mutation 13, Splice Site 5, Frame Shift Del 4, Intron 2, 5'UTR 2, 3'UTR 2, RNA 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNGA3 | c.848G>A p.R283Q | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs104893614, CM980375, COSV55627817; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC9 | c.461A>G p.K154R | Missense Mutation (SNP) | VAF 26/231 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV99685405; called by muse, mutect2, varscan2
- ABHD13 | c.794G>T p.G265V | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101024131; called by muse, mutect2, varscan2
- ACER1 | c.241A>C p.S81R | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100034006; called by muse, mutect2
- ADAM17 | c.1256G>T p.G419V | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as COSV100176200; called by muse, mutect2, varscan2
- ADAM21 | c.1266T>A p.C422* | Nonsense Mutation (SNP) | VAF 10/110 reads (9%) | catalogued as COSV99960873; called by muse, mutect2
- ADAMTS9 | c.5168A>C p.E1723A | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT tolerated (0.97); PolyPhen benign (0.017); catalogued as COSV99899223; called by muse, mutect2, varscan2
- ADCY2 | c.3121C>T p.Q1041* | Nonsense Mutation (SNP) | VAF 8/108 reads (7%) | catalogued as COSV100602557; called by muse, mutect2
- AEN | c.392G>T p.R131L | Missense Mutation (SNP) | VAF 23/212 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100237405; called by muse, mutect2, varscan2
- AL035460.1 | c.197C>A p.S66Y | Missense Mutation (SNP) | VAF 35/214 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.178); catalogued as COSV100730125, COSV63028599; called by muse, mutect2, varscan2
- ALPK2 | c.3575G>T p.R1192M | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as COSV100864304; called by muse, mutect2, varscan2
- ANK3 | c.2671G>C p.E891Q (on ENST00000280772 / NM_001320874.2; = p.E25Q on NM_001149.3) | Missense Mutation (SNP) | VAF 18/207 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55062070, COSV99779502; called by muse, mutect2
- ANKRD26 | c.2795A>G p.K932R | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.391); catalogued as COSV101063127; called by muse, mutect2, varscan2
- ATP8A1 | c.2120G>T p.G707V | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.091); catalogued as COSV100045769; called by muse, mutect2, varscan2
- BARD1 | c.1811-1G>C p.X604_splice | Splice Site (SNP) | VAF 8/39 reads (21%) | catalogued as COSV99638510; called by muse, mutect2, varscan2
- BCORL1 | c.87-2A>G p.X29_splice | Splice Site (SNP) | VAF 21/249 reads (8%) | catalogued as COSV99499176; called by muse, mutect2
- BIRC2 | c.115A>G p.M39V | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV99926648; called by muse, mutect2, varscan2
- BMX | c.1919C>A p.T640N | Missense Mutation (SNP) | VAF 39/279 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV100564419; called by muse, mutect2, varscan2
- BRWD3 | c.2659G>A p.D887N | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.199); catalogued as COSV100955939, COSV64751314; called by muse, mutect2, varscan2
- CCDC38 | c.1591C>A p.L531I | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99900075; called by muse, mutect2, varscan2
- CCDC8 | c.861G>C p.Q287H | Missense Mutation (SNP) | VAF 51/236 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV100282004, COSV56774385, COSV99048784; called by muse, mutect2, varscan2
- CCDC85A | c.584A>T p.Q195L | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.647); catalogued as COSV101339452; called by muse, mutect2
- CD19 | c.286C>A p.L96M | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs751791834, COSV100218027; called by muse, mutect2
- CDCA4 | c.31G>T p.V11F | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV100288177; called by muse, mutect2, varscan2
- CEACAM18 | c.920T>C p.M307T | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as COSV101140312; called by muse, mutect2, varscan2
- CEACAM4 | c.362C>A p.T121N | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99701020; called by muse, mutect2
- CERKL | c.678-2A>G p.X226_splice | Splice Site (SNP) | VAF 14/71 reads (20%) | catalogued as COSV100183537; called by muse, mutect2, varscan2
- CHST14 | c.615C>G p.H205Q | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as COSV100086944; called by muse, mutect2
- CLEC16A | c.877G>A p.V293M | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs771091298, COSV101277890; called by muse, mutect2, varscan2
- COA6 | c.223G>T p.D75Y | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100784563; called by muse, mutect2, varscan2
- COL4A6 | c.586G>T p.G196* | Nonsense Mutation (SNP) | VAF 14/139 reads (10%) | catalogued as COSV100563925; called by muse, mutect2, varscan2
- CSGALNACT2 | c.1219A>G p.N407D | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0.171); catalogued as COSV100989782; called by muse, mutect2
- CSMD3 | c.10654C>A p.L3552I (on ENST00000297405 / NM_001363185.1; = p.L3383I on NM_052900.3) | Missense Mutation (SNP) | VAF 17/192 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52119338; called by muse, mutect2
- DAB2IP | c.1121A>G p.E374G (on ENST00000408936; = p.E346G on NM_032552.3) | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99405226; called by muse, mutect2, varscan2
- DCAF8L1 | c.1012T>C p.Y338H | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101491440; called by muse, mutect2, varscan2
- DCST1 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs772198333, COSV99793016; called by muse, mutect2
- DNAH17 | c.8953G>A p.A2985T | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV101102027; called by muse, mutect2
- DNAH2 | c.2396T>C p.V799A | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV101209208; called by muse, mutect2, varscan2
- DNAI4 | c.2196G>A p.W732* | Nonsense Mutation (SNP) | VAF 25/196 reads (13%) | catalogued as COSV100925487; called by muse, mutect2, varscan2
- DPP10 | c.1832T>G p.I611S | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.219); catalogued as COSV100062738; called by muse, mutect2, varscan2
- EEF1A2 | c.962G>T p.R321L | Missense Mutation (SNP) | VAF 19/166 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.484); catalogued as COSV53206403, COSV99419298; called by muse, mutect2
- EFCAB6 | c.2251T>C p.F751L | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.093); catalogued as COSV99413151; called by muse, mutect2, varscan2
- EMC1 | c.2539A>T p.M847L | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as COSV100916438; called by muse, mutect2
- ERICH3 | c.2394G>A p.W798* | Nonsense Mutation (SNP) | VAF 14/164 reads (9%) | catalogued as COSV100444020; called by muse, mutect2
- ETAA1 | c.2689G>C p.E897Q | Missense Mutation (SNP) | VAF 15/262 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.87); catalogued as COSV99712703; called by muse, mutect2
- FAM135B | c.1378C>A p.L460I | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV52733210, COSV52757897; called by muse, mutect2, varscan2
- FAM13C | c.1477A>C p.K493Q | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.973); catalogued as COSV53247984; called by muse, mutect2, varscan2
- FAT3 | c.4395C>A p.Y1465* | Nonsense Mutation (SNP) | VAF 21/153 reads (14%) | catalogued as COSV53161310, COSV99964840; called by muse, mutect2, varscan2
- FBN2 | c.3925C>A p.L1309I | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV52550783, COSV99326722; called by muse, mutect2
- FBN2 | c.3924C>A p.C1308* | Nonsense Mutation (SNP) | VAF 13/115 reads (11%) | catalogued as COSV99326724; called by muse, mutect2
- FGF23 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 23/182 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs150852442; called by muse, mutect2, varscan2
- FUT9 | c.264C>G p.I88M | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as COSV100133427, COSV56142443; called by muse, mutect2
- FUT9 | c.592C>G p.P198A | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.3); catalogued as rs1408477180, COSV100133428; called by muse, mutect2, varscan2
- GAD1 | c.1040C>T p.T347M | Missense Mutation (SNP) | VAF 19/198 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749452013, COSV100713800; called by muse, mutect2, varscan2
- GDI1 | c.940G>T p.A314S | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT tolerated (0.7); PolyPhen benign (0.27); catalogued as COSV99340993, COSV99341252; called by muse, mutect2
- GLE1 | c.134T>A p.L45Q | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV100012488; called by muse, mutect2, varscan2
- GLUD2 | c.115G>T p.A39S | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.01); catalogued as COSV100046728, COSV60153316; called by muse, mutect2
- GRM7 | c.416G>C p.G139A | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as COSV100736160; called by muse, mutect2, varscan2
- HECTD4 | c.3401G>A p.R1134H | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as rs1317187989, COSV61178017; called by muse, mutect2, varscan2
- HMGB4 | c.211T>C p.Y71H | Missense Mutation (SNP) | VAF 44/269 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99588872; called by muse, mutect2, varscan2
- HP1BP3 | c.511-1G>C p.X171_splice | Splice Site (SNP) | VAF 9/73 reads (12%) | catalogued as COSV100391744; called by muse, mutect2, varscan2
- IGF2R | c.5530G>T p.G1844W | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV100807264, COSV63627876; called by muse, mutect2
- IGF2R | c.5794G>T p.D1932Y | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV100807267; called by muse, mutect2, varscan2
- IL22 | c.263G>C p.R88P | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV100048824; called by muse, mutect2, varscan2
- IRAK1 | c.1258G>T p.G420C | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100888983; called by muse, mutect2, varscan2
- KDR | c.1691A>T p.Q564L | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.124); catalogued as COSV99817384; called by muse, mutect2, varscan2
- KIF2B | c.1477C>A p.P493T | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99275166; called by muse, mutect2, varscan2
- KIF4B | c.2207A>G p.K736R | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV101469236; called by muse, mutect2, varscan2
- KIF5A | c.1841A>G p.E614G | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as COSV99672849; called by muse, mutect2
- KIN | c.136A>G p.M46V | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as COSV100760129; called by muse, mutect2, varscan2
- KMT2D | c.2704G>T p.E902* | Nonsense Mutation (SNP) | VAF 17/145 reads (12%) | catalogued as COSV99980313; called by muse, mutect2, varscan2
- KRT78 | c.1438C>A p.L480M | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as COSV57940572; called by muse, mutect2, varscan2
- LILRB4 | c.551C>A p.P184H | Missense Mutation (SNP) | VAF 17/169 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99553503, COSV99554233; called by muse, mutect2, varscan2
- LRFN5 | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99983281; called by muse, mutect2, varscan2
- LRFN5 | c.1052A>T p.D351V | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99983282; called by muse, mutect2, varscan2
- LRIT3 | c.1366A>C p.K456Q | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.086); catalogued as COSV100016032; called by muse, mutect2
- MAGEB1 | c.986C>G p.A329G | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.36); catalogued as COSV100974928, COSV66775603; called by muse, mutect2
- MANSC1 | c.337G>C p.G113R | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101115811; called by muse, varscan2
- MAP2K5 | c.380G>T p.G127V | Missense Mutation (SNP) | VAF 19/248 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as rs776595115, COSV99460342; called by muse, mutect2
- MMRN2 | c.1549G>A p.E517K | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV100922556; called by muse, mutect2
- MRC1 | c.359G>C p.G120A | Missense Mutation (SNP) | VAF 62/485 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.906); catalogued as COSV100509578; called by muse, mutect2, varscan2
- MUC17 | c.4658C>T p.S1553L | Missense Mutation (SNP) | VAF 66/453 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV60289118; called by muse, mutect2, varscan2
- MYH15 | c.643A>G p.T215A | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.148); catalogued as COSV56311743; called by muse, mutect2
- MYLK | c.4711G>A p.E1571K | Missense Mutation (SNP) | VAF 11/158 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as COSV100658893; called by muse, mutect2
- MYSM1 | c.163A>G p.N55D | Missense Mutation (SNP) | VAF 19/230 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV101284036; called by muse, mutect2
- NFS1 | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV100931892; called by muse, mutect2
- OR10Q1 | c.551G>A p.C184Y | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100372238; called by muse, mutect2, varscan2
- OR2T1 | c.94A>G p.I32V | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100822295; called by muse, mutect2, varscan2
- OR2T11 | c.695A>G p.K232R | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.012); catalogued as COSV100424780; called by muse, mutect2, varscan2
- OR6Y1 | c.445C>A p.L149M | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.641); catalogued as COSV100225336; called by muse, mutect2, varscan2
- OR7A10 | c.833A>C p.Y278S | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV99932426; called by muse, mutect2
- OTUD6B | c.505G>C p.E169Q | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.098); catalogued as COSV99575900; called by muse, mutect2
- PACS1 | c.1491C>G p.S497R | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100269886; called by muse, mutect2, varscan2
- PAQR9 | c.503G>T p.S168I | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100503775; called by muse, mutect2, varscan2
- PDE4B | c.1493T>C p.L498P | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100303152; called by muse, mutect2, varscan2
- POLG | c.1416G>T p.Q472H | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV99174677; called by muse, varscan2
- PRDM10 | c.1180C>T p.R394* | Nonsense Mutation (SNP) | VAF 12/80 reads (15%) | catalogued as rs1256873745, COSV100456709; called by muse, mutect2, varscan2
- QPCT | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.977); catalogued as COSV100621574; called by muse, mutect2, varscan2
- RAB13 | c.108_111del p.Y37Sfs*15 | Frame Shift Del (DEL) | VAF 7/53 reads (13%) | catalogued as rs1403060343; called by mutect2, pindel, varscan2
- RBMX | c.1030A>G p.R344G | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV100284704; called by muse, mutect2
- REG1A | c.344G>T p.S115I | Missense Mutation (SNP) | VAF 59/218 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV99286757; called by muse, mutect2, varscan2
- RPGRIP1L | c.1244-1G>C p.X415_splice | Splice Site (SNP) | VAF 3/30 reads (10%) | catalogued as COSV100046192; called by muse, mutect2
- RYR2 | c.13840G>A p.G4614R | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100769562, COSV63672474; called by muse, mutect2, varscan2
- S100A7 | c.292G>A p.G98R | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as rs1262069983, COSV100906729, COSV64193475, COSV64193557; called by muse, mutect2, varscan2
- SCG5 | c.338A>G p.Y113C | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100276758; called by muse, mutect2
- SDC4 | c.547G>T p.G183C | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101023424; called by muse, mutect2
- SH3GL2 | c.353G>T p.G118V | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101014232; called by muse, mutect2, varscan2
- SLC22A6 | c.1226T>A p.I409N | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100842818; called by muse, mutect2
- SLC22A8 | c.275T>A p.M92K | Missense Mutation (SNP) | VAF 44/292 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV100267839; called by muse, mutect2, varscan2
- SLC44A5 | c.1664T>G p.L555R | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV100901805; called by muse, mutect2, varscan2
- SLC6A19 | c.1728C>G p.I576M | Missense Mutation (SNP) | VAF 11/137 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.255); catalogued as COSV99722235; called by muse, mutect2
- SNX29 | c.2281A>G p.K761E | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as rs1462649595, COSV100028181; called by muse, mutect2
- SON | c.3364C>T p.R1122C | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs767697655, COSV51664638; called by muse, mutect2, varscan2
- ST6GAL1 | c.610G>C p.D204H | Missense Mutation (SNP) | VAF 18/148 reads (12%) | PolyPhen possibly damaging (0.537); catalogued as rs1339877596, COSV99398729; called by muse, mutect2, varscan2
- SYNE1 | c.22650G>T p.R7550S (on ENST00000367255 / NM_182961.4; = p.R7479S on NM_033071.3) | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV99560768; called by muse, mutect2, varscan2
- SYNE1 | c.22649G>T p.R7550M (on ENST00000367255 / NM_182961.4; = p.R7479M on NM_033071.3) | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99560777; called by muse, mutect2, varscan2
- SYNE1 | c.4189G>C p.E1397Q (on ENST00000367255 / NM_182961.4; = p.E1404Q on NM_033071.3) | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV99560785; called by muse, mutect2, varscan2
- TACO1 | c.587G>T p.R196I | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as COSV99366469; called by muse, mutect2, varscan2
- TAF7L | c.350T>C p.L117P | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV100229449; called by muse, mutect2, varscan2
- TAS1R2 | c.1545C>G p.F515L | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1477056175, COSV100946197, COSV64743507; called by muse, mutect2
- TBC1D2 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as rs757556555; called by muse, mutect2, varscan2
- TBL1XR1 | c.1057A>C p.N353H | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101467746; called by muse, mutect2
- TMEM132D | c.1464C>A p.Y488* | Nonsense Mutation (SNP) | VAF 6/62 reads (10%) | catalogued as COSV101242750, COSV67158664; called by muse, mutect2, varscan2
- TMPRSS11E | c.1010T>C p.I337T | Missense Mutation (SNP) | VAF 45/248 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs755615811, COSV100542316; called by muse, mutect2, varscan2
- TRDN | c.1780A>G p.T594A | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.005); catalogued as COSV100521660; called by muse, mutect2, varscan2
- TYK2 | c.2736C>G p.S912R | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99314595; called by muse, mutect2, varscan2
- UGT2B28 | c.997C>T p.Q333* | Nonsense Mutation (SNP) | VAF 14/90 reads (16%) | catalogued as COSV100158720; called by muse, mutect2, varscan2
- UNC13C | c.6602T>A p.V2201E | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV99515354; called by muse, mutect2, varscan2
- UTRN | c.7683G>A p.W2561* | Nonsense Mutation (SNP) | VAF 8/63 reads (13%) | catalogued as COSV100838407; called by muse, mutect2, varscan2
- VCAM1 | c.740C>A p.S247Y | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.707); catalogued as COSV54118675, COSV99658437; called by muse, mutect2, varscan2
- VPS16 | c.1379G>A p.R460Q | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200180667, COSV100988418, COSV66792545; called by muse, mutect2
- WDR27 | c.2285G>T p.G762V | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs770676751, COSV100358627; called by muse, mutect2, varscan2
- XRN1 | c.2272A>G p.K758E | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.053); catalogued as COSV99377760; called by muse, mutect2, varscan2
- ZBED2 | c.568G>T p.E190* | Nonsense Mutation (SNP) | VAF 17/120 reads (14%) | catalogued as COSV99342725; called by muse, mutect2, varscan2
- ZEB2 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV100355758; called by muse, mutect2, varscan2
- ZFPM2 | c.2491G>T p.D831Y | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65873526; called by muse, mutect2
- DLGAP1 | c.2489_2497del p.K830_R832del | In Frame Del (DEL) | VAF 5/53 reads (9%) | called by mutect2, pindel
- IGHV3-20 | c.293T>G p.L98R | Missense Mutation (SNP) | VAF 43/426 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NCOA2 | c.885_892del p.W296Pfs*14 | Frame Shift Del (DEL) | VAF 21/183 reads (11%) | called by mutect2, pindel
- SACS | c.12470del p.G4157Afs*17 | Frame Shift Del (DEL) | VAF 26/200 reads (13%) | called by mutect2, pindel, varscan2
- TOGARAM1 | c.2382del p.F794Lfs*105 | Frame Shift Del (DEL) | VAF 11/65 reads (17%) | called by mutect2, pindel, varscan2
- ZNF605 | c.203G>A p.R68K | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- A1CF | c.1692A>G p.V564= (on ENST00000373993 / NM_138932.2; = p.V556= on NM_014576.4) | Silent (SNP) | VAF 12/144 reads (8%) | catalogued as COSV99255845; called by muse, mutect2
- ABCB1 | c.882A>T p.T294= | Silent (SNP) | VAF 18/140 reads (13%) | catalogued as COSV99712752; called by muse, mutect2, varscan2
- ABCG1 | c.645G>A p.G215= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as rs1490866618, COSV100494055; called by muse, varscan2
- AKAP9 | c.3345C>T p.A1115= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as COSV62341193; called by muse, mutect2, varscan2
- ANK3 | c.3900A>G p.Q1300= (on ENST00000280772 / NM_001320874.2; = p.Q434= on NM_001149.3) | Silent (SNP) | VAF 10/130 reads (8%) | catalogued as COSV99779496; called by muse, mutect2
- BEGAIN | c.756C>G p.T252= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV100766944; called by muse, mutect2, varscan2
- BNIP5 | c.1788C>G p.R596= | Silent (SNP) | VAF 13/178 reads (7%) | catalogued as COSV101465143, COSV101465232; called by muse, mutect2
- C19orf12 | c.249G>T p.P83= (on ENST00000392278 / NM_001031726.3; = p.P72= on NM_031448.6) | Silent (SNP) | VAF 31/186 reads (17%) | catalogued as COSV100080540, COSV60364816; called by muse, mutect2, varscan2
- C5 | c.2286G>A p.K762= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as COSV99797667; called by muse, mutect2, varscan2
- CNN2 | c.426T>C p.I142= | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as rs1333601700, COSV99565600; called by muse, mutect2, varscan2
- COL4A2 | c.2640G>A p.V880= | Silent (SNP) | VAF 10/116 reads (9%) | catalogued as COSV100847313; called by muse, mutect2
- COL6A3 | c.2958C>T p.I986= | Silent (SNP) | VAF 22/256 reads (9%) | catalogued as rs145203676; called by muse, mutect2
- DOCK10 | c.1320T>G p.A440= | Silent (SNP) | VAF 27/185 reads (15%) | catalogued as COSV99288972; called by muse, mutect2, varscan2
- DOK6 | c.715C>T p.L239= | Silent (SNP) | VAF 17/154 reads (11%) | catalogued as rs762299083, COSV101234435; called by muse, mutect2, varscan2
- ELAVL4 | c.315C>T p.N105= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV100836693; called by muse, mutect2, varscan2
- ENTR1 | c.726C>G p.A242= (on ENST00000357365 / NM_001039707.2; = p.A219= on NM_006643.4) | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs369826398; called by muse, mutect2, varscan2
- EPDR1 | c.507C>T p.V169= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV99554345; called by muse, mutect2, varscan2
- FAM47B | c.135C>A p.T45= | Silent (SNP) | VAF 11/89 reads (12%) | catalogued as COSV100264262; called by muse, mutect2, varscan2
- GPRASP1 | c.687C>A p.A229= | Silent (SNP) | VAF 26/358 reads (7%) | catalogued as COSV100850974, COSV64355151; called by muse, mutect2
- GRIK1 | c.2760G>A p.K920= (on ENST00000327783 / NM_001330994.2; = p.K876= on NM_175611.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV100583324, COSV59864820, COSV59870415; called by muse, mutect2
- HAUS1 | c.189T>C p.S63= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as COSV99958865; called by muse, mutect2, varscan2
- IGHV1-24 | c.21C>A p.I7= | Silent (SNP) | VAF 11/113 reads (10%) | called by muse, mutect2
- IGHV3-20 | c.294G>T p.L98= | Silent (SNP) | VAF 45/430 reads (10%) | called by muse, mutect2, varscan2
- ITGAL | c.2415G>A p.L805= | Silent (SNP) | VAF 41/386 reads (11%) | catalogued as COSV63324938; called by muse, mutect2, varscan2
- LAMA4 | c.3978G>C p.L1326= (on ENST00000230538 / NM_001105206.3; = p.L1319= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/80 reads (5%) | catalogued as COSV100038165; called by muse, mutect2
- LTBP3 | c.1281C>G p.L427= | Silent (SNP) | VAF 15/149 reads (10%) | catalogued as COSV100099477; called by muse, mutect2
- MDN1 | c.7494G>A p.L2498= | Silent (SNP) | VAF 12/230 reads (5%) | catalogued as COSV101021174, COSV65518002; called by muse, mutect2
- MIOS | c.210T>G p.L70= | Silent (SNP) | VAF 16/106 reads (15%) | catalogued as COSV100402689; called by muse, mutect2, varscan2
- MYO3A | c.648G>T p.L216= | Silent (SNP) | VAF 12/138 reads (9%) | catalogued as rs771214549; called by muse, mutect2
- NOD2 | c.1773C>T p.V591= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs773962188, COSV56049806; called by muse, mutect2, varscan2
- NOX5 | c.477C>A p.I159= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV99533687; called by muse, mutect2, varscan2
- NUP93 | c.1008G>A p.Q336= | Silent (SNP) | VAF 10/184 reads (5%) | catalogued as COSV100360143; called by muse, mutect2
- OBSL1 | c.1518G>A p.T506= | Silent (SNP) | VAF 9/90 reads (10%) | catalogued as rs1055281369, COSV99216682; called by muse, mutect2, varscan2
- OR5V1 | c.543C>A p.I181= | Silent (SNP) | VAF 26/126 reads (21%) | catalogued as COSV101011218; called by muse, mutect2, varscan2
- OR8B12 | c.711T>C p.F237= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV100172750; called by muse, mutect2, varscan2
- PLIN4 | c.189G>A p.E63= (on ENST00000301286; = p.E78= on NM_001367868.2) | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as COSV100013078; called by muse, mutect2
- PPFIBP2 | c.1656T>C p.N552= | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as COSV100206412; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1000T>C p.L334= (on ENST00000352766; = p.L255= on NM_181334.5) | Silent (SNP) | VAF 14/115 reads (12%) | catalogued as rs770712193, COSV100424163, COSV61232045; called by muse, mutect2, varscan2
- PUM1 | c.2484C>T p.G828= | Silent (SNP) | VAF 50/406 reads (12%) | catalogued as COSV99927856; called by muse, mutect2, varscan2
- REG3A | c.432C>T p.G144= | Silent (SNP) | VAF 44/215 reads (20%) | catalogued as COSV100532657; called by muse, mutect2, varscan2
- RENBP | c.702T>A p.A234= | Silent (SNP) | VAF 15/194 reads (8%) | catalogued as COSV100892408; called by muse, mutect2
- RTL3 | c.369C>A p.S123= | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as COSV58183328; called by muse, mutect2, varscan2
- SERPINA9 | c.570A>T p.I190= | Silent (SNP) | VAF 14/266 reads (5%) | catalogued as COSV100098274; called by muse, mutect2
- SETBP1 | c.2355G>T p.G785= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as COSV99952860; called by muse, mutect2, varscan2
- SIGLEC7 | c.1143G>A p.K381= | Silent (SNP) | VAF 23/95 reads (24%) | catalogued as COSV58317758; called by muse, mutect2, varscan2
- SOD2 | c.264G>A p.L88= | Silent (SNP) | VAF 7/134 reads (5%) | catalogued as rs1208513027, COSV100496603; called by muse, mutect2
- SRI | c.414C>T p.P138= | Silent (SNP) | VAF 12/113 reads (11%) | catalogued as rs778621866, COSV99719759; called by muse, mutect2, varscan2
- SUN1 | c.1827C>T p.L609= (on ENST00000405266 / NM_001367651.1; = p.L489= on NM_025154.6 and 13 other RefSeq transcripts) | Silent (SNP) | VAF 19/105 reads (18%) | catalogued as rs773388807, COSV101273029, COSV67447846; called by muse, mutect2, varscan2
- SYNE1 | c.12688T>C p.L4230= (on ENST00000367255 / NM_182961.4; = p.L4159= on NM_033071.3) | Silent (SNP) | VAF 39/231 reads (17%) | catalogued as COSV99560782; called by muse, mutect2, varscan2
- ZNF208 | c.2433C>G p.G811= | Silent (SNP) | VAF 8/98 reads (8%) | catalogued as COSV101236991; called by muse, mutect2
- ZNF25 | c.735C>T p.L245= | Silent (SNP) | VAF 18/149 reads (12%) | catalogued as rs1256568626, COSV100224580; called by muse, mutect2, varscan2
- ZNF584 | c.1233G>A p.E411= | Silent (SNP) | VAF 14/165 reads (8%) | catalogued as COSV100183270; called by muse, mutect2
- ZNF836 | c.2214G>T p.T738= | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as COSV100440835; called by muse, mutect2, varscan2
- AGAP7P | n.1851A>T | RNA (SNP) | VAF 14/53 reads (26%) | called by mutect2, varscan2
- CPLANE1 | c.*5297T>G | 3'UTR (SNP) | VAF 12/136 reads (9%) | catalogued as COSV99950187, COSV99950287; called by muse, mutect2
- LHFPL3 | c.-3G>T | 5'UTR (SNP) | VAF 6/26 reads (23%) | catalogued as COSV101308281, COSV101308341; called by muse, mutect2, varscan2
- OR8B8 | c.*2A>G | 3'UTR (SNP) | VAF 8/56 reads (14%) | catalogued as COSV100044991; called by muse, mutect2, varscan2
- PHACTR4 | c.1816+555G>C | Intron (SNP) | VAF 7/89 reads (8%) | catalogued as COSV100868433; called by muse, mutect2
- SELENOI | c.-89C>G | 5'UTR (SNP) | VAF 5/22 reads (23%) | catalogued as rs1285776528, COSV99564370; called by muse, mutect2, varscan2
- SNORD64 | n.36A>C | RNA (SNP) | VAF 18/146 reads (12%) | called by muse, mutect2, varscan2
- TPK1 | c.185+15120C>A | Intron (SNP) | VAF 10/90 reads (11%) | called by mutect2, varscan2
